Somatic mutation profile of tumor specimen TARGET-50-PAJNVX-01A (aliquot TARGET-50-PAJNVX-01A-01D) from TARGET case TARGET-50-PAJNVX, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.7 years (1,365 days).
Specimen TARGET-50-PAJNVX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2ca7280-debc-4500-8267-465c0e76d9b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJNVX-10A (Blood Derived Normal), aliquot TARGET-50-PAJNVX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c37f397-474c-4c27-a785-0eeae35f6029

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Frame Shift Del 2, RNA 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6852_6855del p.Y2285Tfs*5 (on ENST00000358273 / NM_001042492.3; = p.Y2264Tfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 19/39 reads (49%) | catalogued as rs1555535032; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 46/49 reads (94%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AIPL1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs781282752, COSV51507292, COSV51508971; called by muse, mutect2, varscan2
- ALDH1L2 | c.1392C>A p.N464K | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV51554037; called by muse, mutect2, varscan2
- BEST3 | c.676G>C p.G226R | Missense Mutation (SNP) | VAF 26/319 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58304679; called by muse, mutect2
- BFSP1 | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 66/227 reads (29%) | catalogued as COSV64901042; called by muse, mutect2, varscan2
- GALNT5 | c.2432G>C p.S811T | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV99375211; called by muse, mutect2, varscan2
- HSPA4 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59181891; called by muse, mutect2, varscan2
- MAGEA11 | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV60758139; called by muse, mutect2, varscan2
- MED1 | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.324); catalogued as COSV56123061; called by muse, mutect2, varscan2
- NLK | c.972C>G p.I324M | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.164); catalogued as COSV63490676, COSV63490719; called by muse, mutect2, varscan2
- SCN11A | c.4417A>T p.I1473F | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV56577925; called by muse, mutect2
- TIMM8B | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs762734929, COSV54780150; called by muse, mutect2
- TSC2 | c.2638_2639+2del p.X880_splice | Splice Site (DEL) | VAF 4/21 reads (19%) | catalogued as rs137854081; ClinVar: not provided; called by mutect2, varscan2
- WDR70 | c.1634G>T p.R545L | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs990467989, COSV54282813; called by muse, mutect2
- BCOR | c.4360_4403del p.R1454Afs*8 (on ENST00000378444 / NM_001123385.2; = p.R1420Afs*8 on NM_017745.6) | Frame Shift Del (DEL) | VAF 51/79 reads (65%) | called by mutect2, pindel, varscan2
- CDH23 | c.1958G>A p.S653N | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TMEM116 | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 199/409 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNNI2 | c.221C>G p.A74G | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- TTN | c.71516G>C p.R23839P (on ENST00000591111; = p.R16415P on NM_003319.4) | Missense Mutation (SNP) | VAF 12/129 reads (9%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF746 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LRRC32 | c.1566C>T p.A522= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs144837505; called by muse, varscan2
- MUC4 | c.1626A>G p.P542= | Silent (SNP) | VAF 49/312 reads (16%) | catalogued as rs1302294180; called by muse, mutect2, varscan2
- NAALADL2 | c.354T>C p.N118= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- OR9A4 | c.258C>T p.L86= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as rs782630687, COSV71885932; called by muse, mutect2
- PRSS41 | c.819G>A p.K273= | Silent (SNP) | VAF 26/162 reads (16%) | called by muse, mutect2, varscan2
- PYGB | c.207C>T p.I69= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs1320651351; called by muse, varscan2
- SREK1 | c.165C>T p.N55= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs538442754, COSV52334764; called by muse, mutect2, varscan2
- TP63 | c.714G>A p.T238= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs773030906, COSV53217700; ClinVar: likely benign; called by muse, mutect2, varscan2
- NBPF7 | n.544G>A | RNA (SNP) | VAF 248/353 reads (70%) | called by muse, mutect2, varscan2
